Somatic mutation profile of tumor specimen MP2PRT-PASLLV-TMP1-A (aliquot MP2PRT-PASLLV-TMP1-A-1-0-D-A80I-36) from MP2PRT case MP2PRT-PASLLV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,281 days).
Specimen MP2PRT-PASLLV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3108071d-31b5-40e6-82f9-7cf03766d921.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASLLV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASLLV-NB1-A-1-0-D-A80I-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cdbb09c2-1e24-4b7d-8852-edbd53cde708

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 15, Silent 7, Nonsense Mutation 2, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 27/337 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, mutect2
- C4orf54 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 70/421 reads (17%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as rs762636080; called by muse, mutect2, varscan2
- CREBBP | c.4427C>G p.P1476R | Missense Mutation (SNP) | VAF 71/263 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52113088, COSV52117573; called by muse, mutect2, varscan2
- LPA | c.2731G>A p.V911I | Missense Mutation (SNP) | VAF 50/335 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as rs932171816, COSV60298455, COSV60306182; called by muse, mutect2, varscan2
- MAGEB10 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 28/436 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.222); catalogued as rs927668854; called by muse, mutect2
- MBP | c.757G>A p.E253K (on ENST00000355994 / NM_001025101.2; = p.E135K on NM_002385.3) | Missense Mutation (SNP) | VAF 27/290 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.873); catalogued as rs1334171636, COSV62828890; called by muse, mutect2
- NOL10 | c.1187G>A p.R396Q | Missense Mutation (SNP) | VAF 28/321 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs762013691, COSV62043592; called by muse, mutect2
- OR8H2 | c.751T>A p.F251I | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV57945659; called by muse, mutect2
- PTPRK | c.107G>A p.C36Y | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774110138; called by muse, mutect2, varscan2
- TRAV24 | c.247C>T p.R83* | Nonsense Mutation (SNP) | VAF 132/486 reads (27%) | catalogued as rs766279812; called by muse, mutect2, varscan2
- WWOX | c.926G>A p.R309H | Missense Mutation (SNP) | VAF 113/374 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs370792938, COSV68350384; called by muse, mutect2, varscan2
- ASB2 | c.841G>T p.D281Y | Missense Mutation (SNP) | VAF 151/785 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CREBBP | c.4562A>T p.D1521V | Missense Mutation (SNP) | VAF 10/220 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCAF8L2 | c.285G>T p.M95I | Missense Mutation (SNP) | VAF 41/396 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FBLL1 | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.06); called by muse, mutect2
- FLT3 | c.2511_2512insGGGCCG p.M837_S838insGP | In Frame Ins (INS) | VAF 33/152 reads (22%) | called by pindel, varscan2
- H1-5 | c.64A>T p.K22* | Nonsense Mutation (SNP) | VAF 42/589 reads (7%) | called by muse, mutect2
- LTB | c.106_107insAG p.V36Efs*12 | Frame Shift Ins (INS) | VAF 144/697 reads (21%) | called by mutect2, pindel, varscan2
- PLXNA2 | c.1850G>A p.G617E | Missense Mutation (SNP) | VAF 185/383 reads (48%) | SIFT tolerated (0.26); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- EFHB | c.1602G>A p.P534= | Silent (SNP) | VAF 21/258 reads (8%) | catalogued as rs201486669, COSV55547283; called by muse, mutect2
- FARP2 | c.1359C>T p.P453= | Silent (SNP) | VAF 36/432 reads (8%) | catalogued as rs1039804494; called by muse, mutect2
- KCNV2 | c.93C>T p.C31= | Silent (SNP) | VAF 38/356 reads (11%) | called by muse, mutect2, varscan2
- LRRC3 | c.358C>T p.L120= | Silent (SNP) | VAF 142/890 reads (16%) | called by muse, mutect2, varscan2
- PDZRN3 | c.2250C>T p.S750= | Silent (SNP) | VAF 101/340 reads (30%) | catalogued as rs762474384; called by muse, mutect2, varscan2
- PRR23B | c.324C>A p.V108= | Silent (SNP) | VAF 32/326 reads (10%) | catalogued as rs575960779; called by muse, mutect2
- TMPRSS11D | c.21A>G p.V7= | Silent (SNP) | VAF 83/241 reads (34%) | called by muse, mutect2, varscan2
